Somatic mutation profile of tumor specimen TCGA-EX-A449-01A (aliquot TCGA-EX-A449-01A-11D-A243-09) from TCGA case TCGA-EX-A449, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; AJCC pathologic stage: Stage IVB; Tumor grade: G1; Age at diagnosis: 42.6 years (15,559 days).
Specimen TCGA-EX-A449-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) def8f236-9361-4803-9549-edc994f58656.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EX-A449-10A (Blood Derived Normal), aliquot TCGA-EX-A449-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f100622c-c79e-47c8-8704-397c8f571f15

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 23, Silent 14, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3951del p.M1318Cfs*163 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as COSV100250056; called by mutect2, pindel, varscan2
- C1QL2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.211); catalogued as rs778909990, COSV55607513; called by muse, mutect2, varscan2
- CHD7 | c.2960G>A p.R987Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.144); catalogued as rs767390470, COSV71113898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNND1 | c.2359G>A p.A787T (on ENST00000399050 / NM_001085458.2; = p.A781T on NM_001331.3) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs771218774, COSV62383336; called by muse, mutect2, varscan2
- DUS3L | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57833388; called by muse, mutect2, varscan2
- DYSF | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50544377; called by muse, mutect2, varscan2
- GLRB | c.701A>G p.K234R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs199963290, COSV100030149; called by mutect2, varscan2
- GSTA4 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV63955818; called by muse, mutect2, varscan2
- JADE2 | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs150023113; called by muse, mutect2
- LRIT1 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV63895049; called by muse, mutect2
- MYH13 | c.4142C>T p.T1381M | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754450155, COSV52840452; called by muse, mutect2, varscan2
- OR4K15 | c.437G>A p.R146H (on ENST00000305051; = p.R122H on NM_001005486.1) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs753243800, COSV100521044, COSV59303142; called by muse, mutect2, varscan2
- P2RX6 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1240024958, COSV53036683; called by mutect2, varscan2
- PPEF1 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62995920, COSV62996504; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, mutect2, varscan2
- SLC6A5 | c.2283C>A p.F761L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV100117159, COSV54225337; called by muse, mutect2
- SLITRK5 | c.2773G>T p.V925L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.441); catalogued as COSV61525698; called by muse, mutect2, varscan2
- TKTL2 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs116616718, COSV54917202, COSV54921786; called by muse, mutect2, varscan2
- TSPAN9 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as rs1444588588, COSV99170972; called by muse, mutect2, varscan2
- XIRP1 | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV100453976; called by muse, mutect2
- ZNF473 | c.623C>A p.P208Q | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); catalogued as COSV54524629, COSV99569104; called by muse, varscan2
- ZNF71 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60149792; called by muse, mutect2, varscan2
- CPT1C | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2
- ABCC2 | c.2148G>A p.K716= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV64986381, COSV64988246; called by muse, mutect2, varscan2
- CACNA1C | c.4842C>T p.T1614= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs779550437, COSV59762326; called by muse, mutect2, varscan2
- CACNA1S | c.3003C>T p.L1001= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV62943019; called by muse, mutect2, varscan2
- CACNB1 | c.543C>T p.L181= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs760550257, COSV60000013; called by muse, mutect2, varscan2
- DEUP1 | c.564C>T p.Y188= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV53215894; called by muse, mutect2, varscan2
- FAM47B | c.963G>A p.P321= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs759087237, COSV61456407; called by muse, mutect2, varscan2
- FAT4 | c.13047A>G p.G4349= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV58704469; called by muse, mutect2, varscan2
- KIR2DL1 | c.192G>C p.G64= | Silent (SNP) | VAF 73/203 reads (36%) | catalogued as COSV52414741; called by muse, mutect2, varscan2
- NDUFB10 | c.195G>T p.V65= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV51910691, COSV51910917; called by muse, mutect2
- PCDHGA5 | c.1710C>T p.D570= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV54004662, COSV54016738; called by muse, mutect2, varscan2
- POLR1F | c.243C>A p.R81= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- PPP3R2 | c.432C>T p.G144= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs763447424, COSV62451901; called by muse, mutect2, varscan2
- PTBP3 | c.1011C>T p.I337= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- SCD5 | c.561C>T p.I187= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV56728725; called by muse, mutect2, varscan2
